Gene-level copy-number profile of tumor specimen TCGA-13-1411-01A from TCGA case TCGA-13-1411, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 81.8 years (29,874 days).
Specimen TCGA-13-1411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.46625639-1e23-44ed-8180-b609dc357e71.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1411-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/517feb42-47b1-47e1-bb45-f23b426fde08

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 3,647; copy number 2: 23,650; copy number 3: 19,054; copy number 4: 9,592; copy number 5: 2,446; copy number 6: 640; copy number 7: 64; copy number 8: 82; copy number 9: 44; copy number 10: 491; copy number 11: 41; copy number 13: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1411-01A-01D-0452-01): tumor purity 0.39, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,552,473–116,965,227, 9 genes: LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P.
- chr13:113,455,819–113,490,951, 3 genes (within-gene range 0–3): DCUN1D2, DCUN1D2-AS, RNU1-16P.
- chr13:113,511,747–113,514,473, 1 gene: AL442125.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,844 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:37,288,137–41,968,366, 73 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:104,126,341–159,233,377, 1,052 genes, copy number 5 (broad region; genes not listed).
- chr8:43,442,902–88,019,113, 641 genes, copy number 5 (broad region; genes not listed).
- chr11:68,980,021–88,524,054, 457 genes, copy number 6 (broad region; genes not listed).
- chr11:88,612,805–88,612,911, 1 gene, copy number 6: RNU6-16P.
- chr12:66,767–34,249,958, 850 genes, copy number 5–11 (broad region; genes not listed).
- chr18:22,798,261–40,247,367, 241 genes, copy number 5–13 (within-gene range 3–13) (broad region; genes not listed).
- chr19:27,638,483–41,027,720, 514 genes, copy number 5–10 (broad region; genes not listed).
- chr20:33,055,424–33,650,036, 15 genes, copy number 5 (within-gene range 2–5): BPIFB3, BPIFB4, BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2.

Autosomal genes at a single copy (total copy number 1): 1,239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
